Surgical pathology report (de-identified scan), TCGA case TCGA-PC-A5DP, project TCGA-SARC (Sarcoma), tissue source site Fox Chase, specimen TCGA-PC-A5DP-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN:
SURGICAL PATHOLOGY REPORT

DOB:
Sex: F
Location:
Date Collected:
Date Received
Physician:
Copy To:
Clinical History/Diagnosis: Sarcoma Infrarenal Vena Cava

ICD-O-3

Leiomyosarcoma NOS
8890/3

Site Retroperitoneum
C48.0

JW 5/24/13

Source of Specimen(s):
1: Biopsy sacral promontory
2: Infrarenal venacava to right common iliac vein and left internal iliac vein

Gross Description:
Received in two parts.
Source of Tissue: 1. Labeled #1, "biopsy sacral promontory"

Frozen Section Diagnosis: 1FS- SPINDLE CELL NEOPLASM PRESENT PEI
(VERIFIED).

Gross Description: Received fresh labeled "biopsy sacral promontory". It consists of a soft light-brown irregular tissue fragment measuring 0.3 x 0.3 x 0.2 cm. The specimen is entirely frozen in 1FS.

Source of Tissue: 2. Labeled #2, "infrarenal vena cava to right common iliac vein and left internal iliac vein"

Gross Description: Received fresh labeled "infrarenal vena cava to right common iliac vein and left internal iliac vein". It consists of a large tan-pink partially encapsulated mass weighing 269 grams and measuring 17 x 12 x 5 cm. The capsule is inked black. The specimen is serially sectioned to reveal a fleshy, soft to firm tan-pink cut surface with multiple scattered areas of focal hemorrhage present. The vessels are completely obliterated by the tumor. Tissue submitted for cytogenetics and representative sections are submitted in 2A-2F.

Designation of Sections: 2A- right common iliac vein margin, 2B- left internal iliac vein margin, 2C- vena cava margin, 2D-2F- additional random sections

Dual/Synch: oncos Primary/Noted		

[page 2 of 2]
Final Diagnosis:

1. Sacral promontory, biopsy:

- Sarcoma present.

2. Infrarenal vena cava to right common iliac vein and left internal iliac vein, resection:

- High grade leiomyosarcoma, 17.0 cm, present at the left internal iliac vein margin.

- Vena cava and right common iliac vein margins are free of tumor.

Procedures/Addenda

Cytogenetics Solid Tumor Date Ordered:

Status

Date Complete:

By:

Date Reported:

Results-Comments

**CYTOGENETIC ANALYSIS REPORTS
TESTING CENTER:**

DIAGNOSIS: Sarcoma

KARYOTYPE: Specimen inadequate for cytogenetic analysis.

RESULTS: The sarcoma sample was harvested after fifteen days in culture. No metaphases were found in a scan of ten slides. The cells failed to grow in culture.

Source: NCI Genomic Data Commons file 039ab992-934c-4315-a72d-a45fbbce7727 (TCGA-PC-A5DP.B2D28BA0-3387-425F-B1B0-EA1EC9635F0A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).